Somatic mutation profile of tumor specimen MMRF_1395_1_BM_CD138pos (aliquot MMRF_1395_1_BM_CD138pos_T1_KAS5U_L00662) from MMRF case MMRF_1395, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.5 years (23,544 days).
Specimen MMRF_1395_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36a9b7d5-9297-4f78-9d70-d87ddfea3182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1395_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1395_1_PB_Whole_C2_KAS5U_L00676; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a08745b2-7851-403e-8d7e-a6157d42ad0b

The open-access MAF lists 96 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 23, Intron 16, Silent 12, Splice Region 2, 3'Flank 2, 5'UTR 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 251/264 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs145985238, COSV53205525; called by muse, mutect2, varscan2
- AFAP1L1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs199689420; called by muse, mutect2, varscan2
- ASTN1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs770986304, COSV56082042; called by muse, mutect2, varscan2
- CLEC6A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.83); PolyPhen benign (0.017); catalogued as rs368271517, COSV101165686; called by muse, mutect2, varscan2
- CSPG4 | c.5368G>A p.G1790S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs373710408; called by muse, mutect2, varscan2
- DEF6 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1257522477; called by muse, mutect2, varscan2
- DSEL | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100025574, COSV59491378; called by muse, mutect2, varscan2
- F2RL3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375264788; called by muse, mutect2, varscan2
- IGHV2-70 | c.157A>C p.M53L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs369368857; called by muse, mutect2, varscan2
- IGKV3-20 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as rs1065532; called by muse, varscan2
- IGLV3-1 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs373605544; called by muse, varscan2
- PANX2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1243934282, COSV50296552; called by muse, mutect2, varscan2
- RFPL2 | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as rs200557290; called by muse, mutect2, varscan2
- TTLL11 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs765628724; called by muse, mutect2, varscan2
- VGLL2 | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV58309075; called by muse, varscan2
- YTHDC1 | c.1862C>T p.P621L (on ENST00000344157 / NM_001031732.4; = p.P603L on NM_133370.4) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.57); catalogued as rs868559889, COSV100704830; called by muse, mutect2, varscan2
- ZFHX4 | c.6718G>T p.V2240F | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV50798860; called by muse, mutect2, varscan2
- COL15A1 | c.3992_4014del p.G1331Vfs*2 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- CYP26C1 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DDOST | c.1357_1358insTTCT p.E453Vfs*9 (on ENST00000415136; = p.E436Vfs*9 on NM_005216.5) | Frame Shift Ins (INS) | VAF 39/45 reads (87%) | called by mutect2, pindel, varscan2
- FAM180A | c.*329+5G>T | Splice Region (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2
- GSPT2 | c.333A>C p.E111D | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV1-69D | c.27T>G p.F9L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, varscan2
- IGLV3-21 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- IL6R | c.813G>C p.K271N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2
- LRGUK | c.1957A>G p.K653E | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MBTPS1 | c.2314G>A p.G772S | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRAP | c.2636A>G p.H879R (on ENST00000359988 / NM_001322945.2; = p.H844R on NM_006175.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- NUP153 | c.1462A>T p.N488Y | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PAG1 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RFX3 | c.2085G>T p.E695D | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- RNF213 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.09); called by muse, mutect2
- SLF2 | c.3013A>G p.N1005D | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TXNIP | c.1141-6C>A | Splice Region (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.3935T>A p.V1312E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ZIC1 | c.70T>C p.S24P | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ZNF225 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF236 | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ADCK5 | c.492C>G p.T164= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- AFAP1 | c.1242C>T p.N414= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs748602184; called by muse, mutect2, varscan2
- ARMC3 | c.1347T>C p.R449= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- DST | c.1665T>C p.Y555= (on ENST00000361203 / NM_001374722.1; = p.Y229= on NM_001723.6) | Silent (SNP) | VAF 61/129 reads (47%) | called by muse, mutect2, varscan2
- HSPA8 | c.423T>C p.N141= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- INPPL1 | c.3582C>T p.S1194= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1353342443, COSV53358068; called by muse, mutect2, varscan2
- MYO15A | c.5061G>A p.P1687= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs376078648; called by muse, mutect2, varscan2
- MYO1C | c.2001A>G p.K667= (on ENST00000648651 / NM_001080779.2; = p.K632= on NM_033375.5) | Silent (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- PASD1 | c.1986G>A p.E662= | Silent (SNP) | VAF 45/51 reads (88%) | called by muse, mutect2, varscan2
- SPTB | c.6816T>C p.D2272= | Silent (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- TTLL13P | c.1497C>T p.F499= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- ZNF469 | c.4182C>T p.A1394= (on ENST00000437464; = p.A1422= on NM_001367624.2) | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs1402676512; called by muse, mutect2, varscan2
- ABCC9 | c.*3296dup | 3'UTR (INS) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- ADH1B | c.19-119G>A | Intron (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2, varscan2
- ANXA1 | c.-14-391C>T | Intron (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- BMP6 | c.*1056_*1057insTTATTA | 3'UTR (INS) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- CBX3 | c.*376del | 3'UTR (DEL) | VAF 36/136 reads (26%) | catalogued as rs767646263; called by mutect2, varscan2*
- CCPG1 | c.*3108A>G | 3'UTR (SNP) | VAF 36/170 reads (21%) | catalogued as rs1314449246; called by muse, mutect2, varscan2
- CHPT1 | c.1176+331T>G | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- CTNND2 | c.2638-1070C>T | Intron (SNP) | VAF 20/57 reads (35%) | catalogued as rs372312820; called by muse, mutect2, varscan2
- CYYR1 | c.*1675A>G | 3'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- DIO2 | c.*277A>G | 3'UTR (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- GRID2 | c.*1407C>G | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- HMHB1 | c.*49G>A | 3'UTR (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- HYDIN | c.2768+66C>T | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.-29A>G | 5'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, varscan2
- ITK | c.*1664C>T | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- KLHL35 | c.1563+40C>T | Intron (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- LAMB1 | c.2458+72G>A | Intron (SNP) | VAF 67/209 reads (32%) | called by muse, mutect2, varscan2
- LIG3 | c.*1650C>G | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- LINC01148 | n.1208C>T | RNA (SNP) | VAF 16/37 reads (43%) | catalogued as rs1029397346; called by muse, mutect2, varscan2
- LTB | c.209-25A>G | Intron (SNP) | VAF 28/70 reads (40%) | catalogued as rs371392111; called by muse, varscan2
- MYB | c.*1001G>A | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, varscan2
- NDUFS8 | c.373-585C>T | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as rs931401841; called by muse, mutect2, varscan2
- PRDM9 | c.*295A>C | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- RAB3IP | c.936+1043G>T | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2
- RAPGEF3 | c.1923+125C>T | Intron (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2
- RAPGEF5 | c.295+1130G>A | Intron (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.*3192A>G | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- SEMA6D | c.*798A>G | 3'UTR (SNP) | VAF 28/78 reads (36%) | catalogued as rs1485030485; called by muse, mutect2, varscan2
- SEPSECS | c.*3799C>T | 3'UTR (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- SESTD1 | c.*5114A>C | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- SH2D4B | chr10:80644589 G>A | 3'Flank (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- SLC12A1 | c.629-2103A>G | Intron (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- SNORA60 | chr20:38447897 T>A | 5'Flank (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SNX9 | c.*95dup | 3'UTR (INS) | VAF 24/69 reads (35%) | catalogued as rs1299554062; called by mutect2, varscan2
- SOCS1 | c.*69A>G | 3'UTR (SNP) | VAF 63/132 reads (48%) | called by muse, mutect2, varscan2
- SYBU | c.*207A>T | 3'UTR (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- TESMIN | c.917+1856G>A | Intron (SNP) | VAF 11/39 reads (28%) | catalogued as rs1287005178; called by muse, mutect2, varscan2
- TMEM213 | c.*3478G>A | 3'UTR (SNP) | VAF 25/73 reads (34%) | catalogued as rs1196283780; called by muse, mutect2, varscan2
- TMPRSS4 | c.-50A>C | 5'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- TRIO | c.7632+787G>A | Intron (SNP) | VAF 41/161 reads (25%) | catalogued as rs758947669, COSV59989373; called by muse, mutect2, varscan2
- TRPM7 | c.*973A>G | 3'UTR (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- UCKL1 | c.1022+32G>A | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as rs752593064; called by muse, mutect2, varscan2
- VAX1 | chr10:117131806 C>T | 3'Flank (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- ZDHHC23 | c.*1221A>G | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- ZHX3 | c.*955G>A | 3'UTR (SNP) | VAF 23/42 reads (55%) | catalogued as rs1455845005, COSV58389743; called by muse, mutect2, varscan2
